Somatic mutation profile of tumor specimen TCGA-UD-AAC1-01A (aliquot TCGA-UD-AAC1-01A-11D-A39R-32) from TCGA case TCGA-UD-AAC1, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.3 years (26,057 days).
Specimen TCGA-UD-AAC1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee20920c-0d83-4670-9727-9494ae9688b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UD-AAC1-10A (Blood Derived Normal), aliquot TCGA-UD-AAC1-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3743491a-b01d-4be4-a593-51f5570b3b3b

The open-access MAF lists 316 somatic variants for this specimen: 220 protein-altering or splice-affecting, 90 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 90, Frame Shift Del 12, Nonsense Mutation 6, Frame Shift Ins 6, In Frame Del 4, Splice Region 4, Intron 3, RNA 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGB | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs121909616, CM920273, COSV57417582, COSV57418841; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- GAA | c.258dup p.N87Qfs*9 | Frame Shift Ins (INS) | VAF 91/129 reads (71%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as rs63751274, CM990865, COSV51881371; ClinVar: pathogenic; called by muse, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 59/83 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 44/71 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs201234441; called by muse, mutect2, varscan2
- ABLIM3 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs757936962, COSV58647978; called by muse, mutect2, varscan2
- ACO2 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); catalogued as rs387907390, COSV53444506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM4 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs201026673; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ALOX15B | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs1247893584, COSV66480188; called by muse, mutect2, varscan2
- ALPK3 | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 67/100 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs147819987; called by muse, mutect2, varscan2
- ANAPC7 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs939569596, COSV101482828; called by muse, mutect2, varscan2
- ANK1 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 95/142 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs745317361; called by muse, mutect2, varscan2
- AP4B1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs748694320; called by muse, mutect2, varscan2
- ARAP1 | c.1762C>T p.R588W (on ENST00000393609 / NM_001040118.2; = p.R343W on NM_015242.4) | Missense Mutation (SNP) | VAF 118/172 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371423117; called by muse, mutect2, varscan2
- ARC | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1466856033; called by muse, mutect2, varscan2
- ARHGAP26 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485178041; called by muse, mutect2, varscan2
- ASL | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs757714252; called by muse, mutect2, varscan2
- ASXL3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772111853; called by muse, mutect2, varscan2
- ATP6V1A | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99850311; called by muse, mutect2, varscan2
- AWAT2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs778820383, COSV99339656; called by muse, mutect2, varscan2
- AXL | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs374067962; called by muse, mutect2, varscan2
- BNC1 | c.2661G>A p.M887I | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99077050; called by muse, mutect2, varscan2
- C20orf194 | c.597dup p.T200Yfs*5 | Frame Shift Ins (INS) | VAF 67/128 reads (52%) | catalogued as rs1221445330; called by mutect2, pindel, varscan2
- C8orf82 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs990202314; called by muse, mutect2, varscan2
- CACTIN | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs374661733; called by muse, mutect2, varscan2
- CAMK2G | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs908594003, COSV59480019; called by muse, mutect2, varscan2
- CAPZA1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99583387; called by muse, mutect2, varscan2
- CASR | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs747090029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.2075C>T p.A692V (on ENST00000341926; = p.A775V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs767408102; called by muse, mutect2, varscan2
- CATSPERD | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 134/185 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200349808, COSV100486725; called by muse, mutect2, varscan2
- CCDC185 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 94/133 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs374835925; called by muse, mutect2, varscan2
- CCNL2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs894402625; called by muse, mutect2, varscan2
- CD27 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs755775043; ClinVar: uncertain significance; called by muse, mutect2
- CDK14 | c.1226C>T p.S409L (on ENST00000380050 / NM_001287135.2; = p.S391L on NM_012395.3) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs754712322, COSV56029154; called by muse, mutect2, varscan2
- CDKN2C | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs750990884; called by muse, mutect2, varscan2
- CES1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778524104, COSV100828659; called by muse, mutect2, varscan2
- CIBAR2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 183/265 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753996502; called by muse, mutect2, varscan2
- CLCNKB | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201540273, CM004244, COSV65161667; called by muse, mutect2, varscan2
- CMTR1 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 24/33 reads (73%) | catalogued as COSV65089690; called by muse, mutect2, varscan2
- CNTNAP2 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as rs375721700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs376333360; called by muse, mutect2, varscan2
- COL8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs765975038; called by muse, mutect2, varscan2
- COPB2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV100300796, COSV60812478; called by muse, mutect2
- CSNK1A1L | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 70/96 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV104429098; called by muse, mutect2, varscan2
- CSTF3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100124361; called by muse, mutect2, varscan2
- CTDP1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs143317014; called by muse, mutect2, varscan2
- DAG1 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 96/142 reads (68%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.499); catalogued as rs760082311, COSV58182826; called by muse, mutect2, varscan2
- DCAF10 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1322423373, COSV54291721; called by muse, mutect2, varscan2
- DCHS1 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1332143389, COSV55034350; called by muse, varscan2
- DENND1C | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 99/144 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780186122, COSV100375156, COSV100375200; called by muse, mutect2, varscan2
- DGKK | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868952791, COSV65707186; called by muse, mutect2, varscan2
- DMD | c.1882_1884del p.L628del | In Frame Del (DEL) | VAF 53/80 reads (66%) | catalogued as rs767034345; called by pindel, varscan2
- DOCK5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs772869298, COSV52400213; called by muse, mutect2, varscan2
- EPHB4 | c.1425C>T p.G475= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs370067368; called by muse, mutect2, varscan2
- ESX1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs557150749; called by muse, varscan2
- FAM53C | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs747747219, COSV53511290; called by muse, mutect2, varscan2
- FAM71F1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs151149484; called by muse, mutect2, varscan2
- FBF1 | c.2036G>A p.R679H (on ENST00000586717; = p.R693H on NM_001319193.1) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as rs778453600; called by muse, mutect2, varscan2
- FBL | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.039); catalogued as rs1376514692, COSV55684206; called by muse, mutect2, varscan2
- FBP2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs765534622; called by muse, mutect2, varscan2
- FCHO1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746424375; called by muse, mutect2, varscan2
- FNIP2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs770340453, COSV52443825; called by muse, mutect2, varscan2
- FRMD4A | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as rs1307114187; called by muse, mutect2, varscan2
- FRMPD3 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 75/105 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs1240210375; called by muse, mutect2, varscan2
- GAL3ST3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 116/172 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV61749517; called by muse, varscan2
- GARRE1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 110/161 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs778258992; called by muse, mutect2, varscan2
- GIPC3 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 65/92 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV59261000; called by muse, mutect2, varscan2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2, varscan2
- GNAS | c.717C>T p.N239= | Splice Region (SNP) | VAF 91/135 reads (67%) | catalogued as rs141552288, COSV99669007; called by muse, mutect2, varscan2
- GPATCH2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 65/86 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775087701, COSV65131237; called by muse, mutect2, varscan2
- GRIA1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs768979604; called by muse, mutect2, varscan2
- GRIN3A | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766942150; called by muse, mutect2, varscan2
- GRM1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV51120417, COSV51179785; called by muse, mutect2, varscan2
- GTF3C1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340597679, COSV62240781; called by muse, mutect2, varscan2
- GUCY1A1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs372152908; called by muse, mutect2, varscan2
- HBS1L | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235557129; called by muse, mutect2, varscan2
- IFT140 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 99/147 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147756729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPPL1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 98/152 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200692358; called by muse, mutect2, varscan2
- IQGAP2 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs1286594449, COSV57167692; called by muse, mutect2, varscan2
- ITIH6 | c.1089C>G p.N363K | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54493397; called by muse, mutect2, varscan2
- JAML | c.649G>A p.G217S (on ENST00000356289 / NM_001098526.2; = p.G207S on NM_153206.3) | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs772971972, COSV99409283; called by muse, mutect2, varscan2
- KCNQ2 | c.1576G>A p.E526K (on ENST00000359125 / NM_172107.4; = p.E498K on NM_004518.6) | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs765124891; called by muse, mutect2, varscan2
- KCNV2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs373963150; called by muse, mutect2, varscan2
- KDM5C | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs782454292, COSV64767859; called by muse, mutect2
- KIF4B | c.2105G>T p.R702L | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70531861; called by mutect2, varscan2
- KIF5C | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV68481050; called by muse, mutect2, varscan2
- KLC1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1224963542; called by muse, mutect2, varscan2
- KLHL31 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 87/148 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as rs1561983899; called by muse, mutect2, varscan2
- KLHL8 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1374619001; called by muse, mutect2, varscan2
- KRT14 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs775519978; called by muse, mutect2, varscan2
- LATS1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53591003, COSV53591320; called by muse, mutect2, varscan2
- LATS2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as rs371775408; called by muse, mutect2, varscan2
- LAX1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763868284, COSV65849196; called by muse, mutect2, varscan2
- LRP1B | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs756168629, COSV67189242, COSV67241168; called by muse, mutect2, varscan2
- LRRC73 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs758930916; called by muse, mutect2, varscan2
- LRRIQ1 | c.2756G>A p.G919D | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1237497598; called by muse, mutect2, varscan2
- LTBR | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as rs763801721; called by muse, mutect2, varscan2
- LYRM1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1037242716; called by muse, mutect2, varscan2
- MAGEC1 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 117/168 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs889190201; called by muse, mutect2, varscan2
- MAN1C1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 103/141 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373813766; called by muse, mutect2, varscan2
- MAP3K4 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as rs763787914; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 52/90 reads (58%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MUC5B | c.9871G>A p.G3291S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs574013648; called by muse, mutect2, varscan2
- MXRA5 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs1174165543, COSV54223661; called by muse, mutect2, varscan2
- NALCN | c.4492C>T p.R1498C | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51927569; called by muse, varscan2
- NCF2 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs369006606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDST2 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV55213962; called by muse, mutect2, varscan2
- NIPBL | c.7199G>A p.R2400H | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765741574; called by muse, mutect2, varscan2
- NIPSNAP2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs1204581640; called by muse, mutect2, varscan2
- NLRP9 | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 120/165 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs199518376, COSV60459247; called by muse, mutect2, varscan2
- NPR3 | c.1059C>T p.Y353= | Splice Region (SNP) | VAF 15/29 reads (52%) | catalogued as rs373766629; called by muse, varscan2
- NR4A1 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 79/114 reads (69%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs576515948; called by muse, mutect2, varscan2
- NRG2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs1445926672; called by muse, mutect2, varscan2
- NUDT1 | c.161G>A p.R54Q (on ENST00000397048 / NM_198952.1; = p.R31Q on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs139825597; called by muse, mutect2, varscan2
- NVL | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs971565927; called by muse, mutect2, varscan2
- OR5L1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 90/124 reads (73%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs534141468, COSV61732926; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.691G>A p.V231I (on ENST00000259318 / NM_001136562.3; = p.V462I on NM_007203.5) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs139564817, COSV52173723; called by muse, mutect2, varscan2
- PAPOLG | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371577666, COSV53183814; called by muse, mutect2, varscan2
- PARD6A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 146/218 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1490786668, COSV99538065; called by muse, mutect2, varscan2
- PCDHB7 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1563919346, COSV50758999, COSV99175216; called by muse, mutect2, varscan2
- PCDHB9 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.742); catalogued as rs782808992; called by muse, mutect2, varscan2
- PCDHGB1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV53975285; called by muse, mutect2, varscan2
- PEX1 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as rs200991412, COSV50402539; called by muse, mutect2, varscan2
- PISD | c.556G>A p.V186M (on ENST00000439502 / NM_001326412.1; = p.V152M on NM_014338.3) | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as rs201154270; called by muse, mutect2, varscan2
- PKN1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 93/133 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs750717632; called by muse, mutect2, varscan2
- PLEKHG4B | c.2434G>A p.E812K (on ENST00000283426; = p.E1168K on NM_052909.5) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770404592, COSV99360763; called by muse, mutect2, varscan2
- PROX1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 98/139 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99798926; called by muse, mutect2, varscan2
- PTPRE | c.1464C>T p.D488= | Splice Region (SNP) | VAF 58/87 reads (67%) | catalogued as rs571645848; called by muse, mutect2, varscan2
- RAB1B | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as rs1334640022; called by muse, mutect2, varscan2
- RAB3D | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 189/258 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.352); catalogued as rs368384189; called by muse, mutect2, varscan2
- RALGAPA1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746208135; called by muse, varscan2
- RASGRP1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 99/136 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs888821403, COSV60366933; called by muse, mutect2, varscan2
- REEP4 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 134/202 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs187812402; called by muse, mutect2, varscan2
- RELL2 | c.564del p.T189Qfs*44 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | catalogued as COSV51836469; called by mutect2, pindel, varscan2
- RRP1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.116); catalogued as rs766713616; called by muse, mutect2, varscan2
- RSPH10B2 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs775750499; called by muse, mutect2, varscan2
- RYR2 | c.4274C>T p.T1425M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs761181641, COSV63661890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBF1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62367940; called by muse, mutect2, varscan2
- SCN11A | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753507140, COSV56574301; called by muse, mutect2, varscan2
- SDK1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs547185174, COSV67373532; called by muse, mutect2, varscan2
- SEC24B | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs754176318, COSV54498619; called by muse, mutect2, varscan2
- SGSH | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs552049399, COSV58339334; called by muse, mutect2, varscan2
- SLC12A1 | c.2242del p.Y748Mfs*22 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs758961147; called by mutect2, pindel
- SLC13A4 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.675); catalogued as rs146102275; called by muse, mutect2, varscan2
- SLC1A6 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV99694279; called by muse, mutect2, varscan2
- SLC36A3 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs758913228, COSV58855938; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 41/63 reads (65%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC8A2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs764308545, COSV99369579; called by muse, mutect2, varscan2
- SLC9A1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 77/121 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1309855858, COSV56053097; called by muse, mutect2, varscan2
- SMARCA5 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs868118261; called by muse, mutect2, varscan2
- SMTN | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766340468, COSV60779289; called by muse, mutect2, varscan2
- SPECC1 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1453502151, COSV54953056; called by muse, mutect2, varscan2
- SPINK5 | c.1822del p.Q608Sfs*107 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as COSV99807665; called by mutect2, pindel, varscan2
- SPN | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 147/214 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs779631820, COSV64070234; called by muse, mutect2, varscan2
- SUOX | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 138/202 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs535313141, COSV99906960; called by muse, mutect2, varscan2
- SURF1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs782157083, COSV59297719; called by muse, mutect2, varscan2
- TBC1D9B | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as rs776480425; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TENM2 | c.2197G>A p.D733N (on ENST00000518659 / NM_001122679.2; = p.D501N on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1371911013, COSV69134523, COSV69134766; called by muse, mutect2, varscan2
- THADA | c.5428_5429del p.S1810* | Frame Shift Del (DEL) | VAF 60/120 reads (50%) | catalogued as rs1558439485; called by pindel, varscan2
- TJP1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs745465485; called by muse, mutect2, varscan2
- TMCC2 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs753627770, COSV58001678, COSV58005688; called by muse, mutect2, varscan2
- TMTC2 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1341846388, COSV58258896, COSV58284464; called by muse, mutect2, varscan2
- TNR | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200605845, COSV54906301; called by muse, mutect2, varscan2
- TRAF1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 94/130 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs766666979, COSV100875098; called by muse, mutect2, varscan2
- TRPC1 | c.829C>T p.R277W (on ENST00000476941 / NM_001251845.2; = p.R243W on NM_003304.4) | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763511368, COSV56424578; called by muse, mutect2, varscan2
- TSNARE1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs566616065; called by muse, mutect2, varscan2
- TTL | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 74/106 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs774162883; called by muse, mutect2, varscan2
- UBASH3A | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151042130; called by muse, mutect2, varscan2
- USP25 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs200318307, COSV53481343; called by muse, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 32/62 reads (52%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR91 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 118/253 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs777254234, COSV60371737; called by muse, mutect2, varscan2
- WWP2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 112/161 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs763693568; called by muse, mutect2, varscan2
- ZBTB20 | c.326G>A p.R109H (on ENST00000474710 / NM_001164342.2; = p.R36H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100614310; called by muse, mutect2
- ZC3H4 | c.2991del p.V998Cfs*146 | Frame Shift Del (DEL) | VAF 103/184 reads (56%) | catalogued as COSV99452581; called by mutect2, pindel, varscan2
- ZCCHC2 | c.2524G>A p.A842T | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs373529654, COSV54035878; called by muse, varscan2
- ZNF354B | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs986499660; called by muse, mutect2, varscan2
- ZNF638 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs1295272375; called by muse, mutect2, varscan2
- APEH | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARID2 | c.3416dup p.V1140Sfs*20 | Frame Shift Ins (INS) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- CENPF | c.7117dup p.I2373Nfs*28 | Frame Shift Ins (INS) | VAF 32/62 reads (52%) | called by mutect2, pindel, varscan2
- CIC | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CSMD1 | c.3316G>A p.G1106R (on ENST00000520002; = p.G1105R on NM_033225.6) | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCHS1 | c.4643C>T p.S1548L | Missense Mutation (SNP) | VAF 109/147 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EHF | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXTL1 | c.1283del p.P428Qfs*6 | Frame Shift Del (DEL) | VAF 75/149 reads (50%) | called by mutect2, pindel, varscan2
- FBXO38 | c.2752C>T p.Q918* (on ENST00000340253 / NM_205836.3; = p.Q843* on NM_030793.5) | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- GALNT2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLYAT | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- GRM5 | c.1525T>C p.S509P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTT | c.1048_1050del p.S350del | In Frame Del (DEL) | VAF 25/42 reads (60%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- LATS2 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIMCH1 | c.246_248del p.I83del | In Frame Del (DEL) | VAF 18/29 reads (62%) | called by pindel, varscan2
- LOX | c.632-2A>T p.X211_splice | Splice Site (SNP) | VAF 93/221 reads (42%) | called by muse, mutect2, varscan2
- LRATD2 | c.378_391del p.Q127Afs*8 | Frame Shift Del (DEL) | VAF 126/208 reads (61%) | called by mutect2, pindel, varscan2
- NEXMIF | c.1143C>A p.D381E | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUDT21 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDE4A | c.2026C>T p.R676W (on ENST00000380702 / NM_001111307.2; = p.R437W on NM_006202.3) | Missense Mutation (SNP) | VAF 137/215 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHLPP2 | c.3406_3408del p.A1136del | In Frame Del (DEL) | VAF 72/125 reads (58%) | called by mutect2, pindel, varscan2
- PIDD1 | c.2434del p.V812Cfs*132 | Frame Shift Del (DEL) | VAF 42/71 reads (59%) | called by mutect2, pindel, varscan2
- PRR18 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 81/121 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSD2 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RADIL | c.2684dup p.H896Afs*18 | Frame Shift Ins (INS) | VAF 62/187 reads (33%) | called by mutect2, pindel, varscan2
- RAI14 | c.1040A>T p.D347V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RIPOR3 | c.2303A>T p.Y768F | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTN4RL2 | c.967C>A p.R323S | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SEPTIN9 | c.1702G>A p.G568S (on ENST00000427177 / NM_001113491.2; = p.G550S on NM_006640.4) | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.99); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SETDB1 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 75/116 reads (65%) | called by muse, mutect2, varscan2
- SHROOM1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- SNRNP27 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SRRM3 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2
- ST8SIA4 | c.306del p.F102Lfs*17 | Frame Shift Del (DEL) | VAF 82/228 reads (36%) | called by mutect2, pindel, varscan2
- TESK2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT tolerated (0.27); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRIML2 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WNT7B | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF282 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZNF358 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCG2 | c.915G>A p.V305= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as rs755743728; called by muse, mutect2, varscan2
- ANKRD55 | c.1587C>G p.V529= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV61951639; called by muse, mutect2, varscan2
- ARMC6 | c.612C>T p.H204= (on ENST00000392336; = p.H179= on NM_033415.4) | Silent (SNP) | VAF 98/146 reads (67%) | catalogued as rs532717577, COSV54180282; called by muse, mutect2, varscan2
- ATP5PF | c.48C>T p.A16= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as rs771159388; called by muse, varscan2
- BICRA | c.1773C>T p.S591= | Silent (SNP) | VAF 23/35 reads (66%) | called by muse, mutect2, varscan2
- C6 | c.2517C>T p.D839= | Silent (SNP) | VAF 73/168 reads (43%) | catalogued as rs567176554, COSV54707923; called by muse, mutect2, varscan2
- CASZ1 | c.1521C>T p.D507= | Silent (SNP) | VAF 91/137 reads (66%) | catalogued as rs1476430347; called by muse, mutect2, varscan2
- CD79A | c.357C>T p.C119= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs138454344; called by muse, mutect2, varscan2
- CIT | c.5964G>A p.T1988= | Silent (SNP) | VAF 59/84 reads (70%) | catalogued as rs772283770; called by muse, mutect2, varscan2
- COL12A1 | c.3534C>T p.S1178= | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as rs747982811, COSV59414573; ClinVar: likely benign; called by muse, mutect2, varscan2
- COPA | c.3195C>T p.S1065= | Silent (SNP) | VAF 65/94 reads (69%) | catalogued as rs756147600; called by muse, mutect2, varscan2
- CORIN | c.2772G>A p.T924= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as rs143980903, COSV99903969; called by muse, mutect2, varscan2
- CSTB | c.174C>T p.H58= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as rs763095750, COSV52366973; ClinVar: likely benign; called by muse, mutect2, varscan2
- CWC22 | c.1143T>A p.V381= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- DENND5A | c.747C>T p.Y249= | Silent (SNP) | VAF 57/86 reads (66%) | catalogued as rs199768980; called by muse, mutect2, varscan2
- DIDO1 | c.6093C>T p.S2031= | Silent (SNP) | VAF 95/129 reads (74%) | catalogued as rs775572924; called by muse, mutect2, varscan2
- DOC2A | c.852C>T p.N284= | Silent (SNP) | VAF 138/208 reads (66%) | catalogued as rs778728323, COSV58751387; called by muse, mutect2, varscan2
- DOC2A | c.681G>A p.A227= | Silent (SNP) | VAF 100/151 reads (66%) | catalogued as rs769227502, COSV58750545; called by muse, mutect2, varscan2
- DPEP2 | c.252G>A p.P84= | Silent (SNP) | VAF 90/140 reads (64%) | catalogued as rs750591596; called by muse, mutect2, varscan2
- DYNC2H1 | c.5985G>A p.A1995= | Silent (SNP) | VAF 87/120 reads (73%) | catalogued as rs771297555, COSV62094709; called by muse, mutect2, varscan2
- FAM234B | c.1653C>T p.N551= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs371966622; called by muse, mutect2, varscan2
- FAT4 | c.4227C>T p.H1409= | Silent (SNP) | VAF 88/127 reads (69%) | catalogued as rs748415854; called by muse, mutect2, varscan2
- FBN2 | c.7497G>A p.P2499= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs756747736; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN3 | c.2865G>A p.P955= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as rs749171861, COSV54467103; called by muse, mutect2, varscan2
- FBXL18 | c.72C>T p.D24= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs372429195; called by muse, mutect2, varscan2
- FCGBP | c.7689C>T p.F2563= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs555357841; called by mutect2, varscan2
- FCGBP | c.1572C>T p.R524= | Silent (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- FGFR3 | c.987G>A p.S329= | Silent (SNP) | VAF 89/125 reads (71%) | catalogued as rs538448784; called by muse, mutect2, varscan2
- FRY | c.8919C>T p.T2973= | Silent (SNP) | VAF 71/104 reads (68%) | catalogued as rs543758530; called by muse, mutect2, varscan2
- GABRR1 | c.1011C>T p.R337= | Silent (SNP) | VAF 80/117 reads (68%) | catalogued as rs185458142, COSV65619626, COSV65620358; called by muse, mutect2, varscan2
- GAL3ST3 | c.663C>T p.A221= | Silent (SNP) | VAF 143/212 reads (67%) | catalogued as rs750205515; called by muse, varscan2
- GIMAP1 | c.642G>A p.E214= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs761557918, COSV100212075; called by muse, mutect2, varscan2
- GLI2 | c.84G>A p.P28= | Silent (SNP) | VAF 71/99 reads (72%) | catalogued as rs377702863; called by muse, mutect2, varscan2
- GRIA1 | c.2193C>A p.P731= | Silent (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.942G>A p.A314= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs762412341, COSV99977193; called by muse, mutect2, varscan2
- HOOK2 | c.1809C>T p.Y603= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs572386190, COSV53403312; called by muse, mutect2, varscan2
- IRF5 | c.1179C>T p.F393= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs756068460; called by muse, mutect2, varscan2
- KCNMB1 | c.327C>T p.S109= | Silent (SNP) | VAF 73/160 reads (46%) | catalogued as rs150688547; called by muse, varscan2
- KIF13A | c.216C>T p.Y72= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as rs780637612, COSV52460721; called by muse, mutect2, varscan2
- LMAN2 | c.861C>T p.I287= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs1434943357; called by muse, mutect2, varscan2
- LPAR3 | c.783C>T p.L261= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs775318808, COSV65453846; called by muse, mutect2, varscan2
- LRRK2 | c.4518C>T p.N1506= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as rs202109311; called by muse, mutect2, varscan2
- LYPD5 | c.282G>A p.P94= (on ENST00000377950 / NM_001031749.3; = p.P51= on NM_182573.2) | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs534504699; called by muse, mutect2, varscan2
- MFHAS1 | c.2976G>A p.S992= | Silent (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- MYH1 | c.330C>T p.Y110= | Silent (SNP) | VAF 74/103 reads (72%) | catalogued as COSV55443394; called by muse, mutect2, varscan2
- NCOA7 | c.2046C>T p.Y682= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as rs749847148, COSV57652052; called by muse, mutect2, varscan2
- NEU2 | c.1062C>T p.Y354= | Silent (SNP) | VAF 136/184 reads (74%) | catalogued as rs756971018, COSV52091510; called by muse, mutect2, varscan2
- NOD1 | c.564C>T p.T188= | Silent (SNP) | VAF 100/220 reads (45%) | catalogued as rs372733312; called by muse, mutect2, varscan2
- OR14I1 | c.465C>T p.A155= | Silent (SNP) | VAF 95/143 reads (66%) | catalogued as rs769530303, COSV61199244; called by muse, mutect2, varscan2
- PAQR4 | c.804C>T p.H268= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as rs531023235, COSV99234297; called by muse, mutect2, varscan2
- PAQR6 | c.963T>C p.L321= (on ENST00000292291 / NM_001272108.2; = p.F239S on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/133 reads (68%) | called by muse, mutect2, varscan2
- PARP12 | c.1293C>T p.A431= | Silent (SNP) | VAF 99/270 reads (37%) | catalogued as rs370234955; called by muse, mutect2, varscan2
- PDSS1 | c.801C>T p.T267= | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as rs759224454, COSV66060055; called by muse, mutect2, varscan2
- PHF20L1 | c.969A>G p.E323= | Silent (SNP) | VAF 62/83 reads (75%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4938G>A p.T1646= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs782196500, COSV62799420; called by muse, mutect2, varscan2
- PM20D1 | c.702C>T p.I234= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs749295349, COSV65648426; called by muse, mutect2, varscan2
- PTPRE | c.1518G>A p.T506= | Silent (SNP) | VAF 59/79 reads (75%) | catalogued as rs781209376; called by muse, mutect2, varscan2
- RADIL | c.300C>T p.Y100= | Silent (SNP) | VAF 93/251 reads (37%) | catalogued as rs756996157, COSV68202501; called by muse, mutect2, varscan2
- RASL12 | c.252C>T p.C84= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1282784433, COSV54981328; called by muse, mutect2
- RIMKLA | c.978G>A p.P326= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as rs763391001; called by muse, mutect2, varscan2
- SALL1 | c.2001C>T p.S667= | Silent (SNP) | VAF 135/226 reads (60%) | catalogued as rs777324988; called by muse, mutect2, varscan2
- SDK2 | c.2385G>A p.P795= | Silent (SNP) | VAF 83/104 reads (80%) | catalogued as rs200600787; called by muse, mutect2, varscan2
- SELENOO | c.666C>T p.S222= | Silent (SNP) | VAF 71/104 reads (68%) | catalogued as rs774257219; called by muse, mutect2, varscan2
- SGSM3 | c.1074C>T p.A358= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as rs757913776; called by muse, mutect2, varscan2
- SHPK | c.249C>T p.S83= | Silent (SNP) | VAF 105/162 reads (65%) | catalogued as rs767681997, COSV99843711; called by muse, mutect2, varscan2
- SLX4 | c.2787G>A p.P929= | Silent (SNP) | VAF 86/135 reads (64%) | catalogued as rs766824198; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMYD4 | c.1236C>T p.C412= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as rs139637633; called by muse, mutect2, varscan2
- SNTB2 | c.1581G>A p.T527= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as rs763339742; called by muse, mutect2, varscan2
- SNX29 | c.2028C>T p.H676= | Silent (SNP) | VAF 51/85 reads (60%) | catalogued as rs368460786; called by muse, mutect2, varscan2
- SPI1 | c.441C>T p.D147= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs767099916; called by muse, mutect2, varscan2
- SPTBN5 | c.10167G>A p.A3389= | Silent (SNP) | VAF 53/78 reads (68%) | catalogued as rs374058564; called by muse, mutect2, varscan2
- SYNPO | c.1800C>T p.G600= (on ENST00000394243 / NM_001166208.2; = p.G356= on NM_007286.6) | Silent (SNP) | VAF 171/387 reads (44%) | catalogued as rs979941681; called by muse, mutect2, varscan2
- TBC1D10C | c.654T>C p.A218= | Silent (SNP) | VAF 62/88 reads (70%) | called by muse, mutect2, varscan2
- TCF25 | c.1566C>T p.N522= | Silent (SNP) | VAF 89/126 reads (71%) | catalogued as rs146680683; called by muse, mutect2, varscan2
- THBS4 | c.132C>T p.G44= | Silent (SNP) | VAF 79/185 reads (43%) | catalogued as rs367779999; called by muse, mutect2, varscan2
- TIE1 | c.177G>A p.P59= | Silent (SNP) | VAF 81/103 reads (79%) | catalogued as COSV65251287; called by muse, mutect2, varscan2
- TNK2 | c.579C>T p.Y193= | Silent (SNP) | VAF 62/91 reads (68%) | catalogued as rs371404236; called by muse, mutect2, varscan2
- TRPM1 | c.1839C>T p.H613= | Silent (SNP) | VAF 103/139 reads (74%) | catalogued as rs377099385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPAN17 | c.726G>A p.A242= | Silent (SNP) | VAF 67/209 reads (32%) | catalogued as rs779925466; called by muse, mutect2, varscan2
- USP8 | c.2976G>T p.R992= | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2
- VPS13D | c.12690G>A p.P4230= | Silent (SNP) | VAF 111/163 reads (68%) | catalogued as rs1364997854; called by muse, mutect2, varscan2
- WDR59 | c.276C>T p.D92= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as rs746761230, COSV100049029; called by muse, mutect2, varscan2
- WDR62 | c.4461G>A p.T1487= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs746402119; called by muse, mutect2, varscan2
- WDR91 | c.1551G>A p.P517= | Silent (SNP) | VAF 122/302 reads (40%) | catalogued as rs767662524, COSV60368383; called by muse, mutect2, varscan2
- XKR8 | c.525G>A p.S175= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as rs371532571; called by muse, mutect2, varscan2
- ZFP64 | c.1731G>A p.T577= | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as rs1157627900; called by muse, mutect2, varscan2
- ZNF2 | c.642C>T p.Y214= (on ENST00000611147 / NM_001291605.2; = p.Y201= on NM_021088.4) | Silent (SNP) | VAF 118/161 reads (73%) | catalogued as rs752724819; called by muse, mutect2, varscan2
- ZNF609 | c.438G>A p.A146= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as rs778288032, COSV58585092; called by muse, mutect2, varscan2
- ZNF654 | c.3183T>C p.L1061= | Silent (SNP) | VAF 75/106 reads (71%) | catalogued as rs781631360; called by muse, varscan2
- ZSCAN1 | c.327C>T p.A109= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs1350923973, COSV56601815; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27631C>T | Intron (SNP) | VAF 24/34 reads (71%) | catalogued as rs780745123, COSV100942473; called by muse, mutect2, varscan2
- HUWE1 | c.1490-606G>A | Intron (SNP) | VAF 13/57 reads (23%) | catalogued as rs1450285056; called by muse, mutect2, varscan2
- MIR548I4 | n.43C>T | RNA (SNP) | VAF 16/20 reads (80%) | catalogued as rs768489206; called by muse, mutect2, varscan2
- NSD3 | c.1855+864G>A | Intron (SNP) | VAF 82/284 reads (29%) | called by muse, mutect2, varscan2
- PYY3 | n.71C>T | RNA (SNP) | VAF 85/116 reads (73%) | catalogued as rs782484828; called by muse, mutect2, varscan2
- RTEL1 | c.*41G>A | 3'UTR (SNP) | VAF 14/18 reads (78%) | catalogued as rs544271988; called by muse, mutect2, varscan2
